CCDI case PBBXCB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/5d707d5b-fac5-4fb2-8957-9ba471200d3b

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.2 years (4,078 days).

Biospecimens (3 samples)
- Sample 0DK1V4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK1WC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DK1WH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
